Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7IZ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7IZ-01A (Primary Tumor).

ICD 0-3

Astrocytoma, grade III
9401/3

Site Brain, supratentorial
C71.0
AD 9/30/13

Glioma with anaplasia
IDH1 R152 mutation present
14/14 q wild type

Diagnosis: anaplastic astrocytoma WHO grade III

untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 8ad0377e-8548-4894-bbe3-5bbb10b57c3d (TCGA-S9-A7IZ.82CF208A-A8F2-4BE1-85DF-C6145FCC6B19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).